Gene-level copy-number profile of tumor specimen TCGA-34-7107-01A from TCGA case TCGA-34-7107, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage II; Age at diagnosis: 70.3 years (25,677 days).
Specimen TCGA-34-7107-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f523b0c7-884b-43b5-b6f8-aa4a480e1a66.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-7107-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e64a4bdc-694f-4dad-a2af-ce98ba527e3d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 18; copy number 2: 15,917; copy number 3: 18,547; copy number 4: 15,872; copy number 5: 4,877; copy number 6: 3,869; copy number 7: 12; copy number 8: 58; copy number 11: 41; copy number 12: 6; copy number 16: 569; copy number 24: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-7107-01A-11D-1943-01): tumor purity 0.59, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 703 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:177,111,036–180,007,297, 63 genes, copy number 8–11 (broad region; genes not listed).
- chr3:91,356,755–96,814,407, 29 genes, copy number 24: ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr3:169,931,998–198,222,513, 569 genes, copy number 16 (within-gene range 6–16) (broad region; genes not listed).
- chr7:67,769,629–68,119,209, 4 genes, copy number 7: AC092648.1, AC092637.1, AC006013.1, MTCO1P57.
- chr8:43,672,823–46,028,892, 3 genes, copy number 7: AC139365.2, AC139365.1, AC118650.1.
- chr12:43,835,967–46,373,778, 32 genes, copy number 8 (within-gene range 4–8): TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2.
- chr12:46,384,233–46,407,166, 3 genes, copy number 8: AC025031.1, AC025031.4, AC025031.5.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
